TCGA case TCGA-B6-A0WX — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a482fc4c-ff1d-46a0-a968-7df06422cc4b

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 40 years; Vital status: Dead; Days to death: 639 days (1.7 years).

Diagnoses (2)
1. Lobular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 40.5 years (14,784 days); Year of diagnosis: 1998; Method of diagnosis: Excisional Biopsy; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 9; Lymph nodes tested: 21; Micrometastasis present: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Lobular carcinoma, NOS), site: Bone, NOS. Age at diagnosis: 42.0 years (15,347 days); Days to diagnosis: 563 days (1.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Locoregional Site, for recurrent disease.

Follow-up (2 entries)
- Day 563 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 563 days (1.5 years).
- Days to follow up: 639 days (1.7 years); Disease response: With Tumor.

Molecular and laboratory tests
- ESR1 (IHC): Negative.
- PGR (IHC): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B6-A0WX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 300 mg.
  Slide TCGA-B6-A0WX-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
  Slide TCGA-B6-A0WX-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-B6-A0WX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B6-A0WX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor; Er positivity method: Image Analysis; Pr positivity define method: Image Analysis; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Pleomorphic/lobular; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: No; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left.
- Follow-up form: Tumor status: With tumor; New tumor event type: Distant Metastasis; New tumor event site: Bone; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 639 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 639 days; disease-free interval: event (new tumor event after initially disease-free), 563 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 563 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B6-A0WX-01A-11D-A107-01): tumor purity 0.34, ploidy 3.78, whole-genome doublings 1.
